Surgical pathology report (de-identified scan), TCGA case TCGA-KO-8404, project TCGA-KICH (Kidney Chromophobe), tissue source site MD Anderson Cancer Center, specimen TCGA-KO-8404-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY, ADRENAL GLAND AND INFERIOR VENA CAVA:

CHROMOPHOBE RENAL CELL CARCINOMA, FUHRMAN'S NUCLEAR GRADE 4 WITH EXTENSIVE SARCOMATOID DEDIFFERENTIATION. (SEE COMMENT)

TUMOR EXTENDS INTO THE PERINEPHRIC AND RENAL SINUS ADIPOSE TISSUE.

TUMOR EXTENDS INTO THE ADRENAL GLAND.

TUMOR MEASURES 18 CM IN GREATEST DIMENSION.

TUMOR INVOLVES THE WALL OF THE RENAL VEIN/INFERIOR VENA CAVA AT THE MARGIN OF RESECTION.

(SEE COMMENT)

Ureteral, renal artery and soft tissue margins of resection, free of tumor.

Renal cortical (simple) cyst (2.2 cm in maximum dimension)

COMMENT

The tumor demonstrates extensive areas of sarcomatoid dedifferentiation composed of spindle cells with sheets of multinucleated giant cells. The sarcomatoid component comprises approximately 90-95% of the tumor. Although grossly the renal vein/inferior vena cava margin of resection appeared to be free of tumor, microscopically the tumor is involving the wall of the renal vein/inferior vena cava at the margin of resection.

GROSS DESCRIPTION

(A) RIGHT KIDNEY, ADRENAL GLAND, INFERIOR VENA CAVA - A nephrectomy specimen (22.0 x 15.4 x 8.0 cm) with attached adrenal gland (5.0 x 4.0 x 2.0 cm) and ureter (8.0 x 0.5 cm).

An 18.0 x 14.0 x 12.0 cm partially cystic, tan, necrotic, hemorrhagic tumor penetrates the renal capsule, extending into the perirenal adipose tissue and appears to involve the attached adrenal gland. The tumor does appear to involve the renal sinus. The aforementioned cystic regions are filled with yellow mucinous material. No papillary excrescences or masses involve the cyst walls. The largest cystic area measures 3.9 cm in greatest dimension and has a thick tan corrugated wall.

3.0 cm away from the primary tumor is a simple 2.2 x 2.0 x 1.0 cm cortical cyst. This cyst is lined by thin unremarkable lining.

The distal ureter, renal vein, and renal artery margins are grossly uninvolved by tumor. However, upon opening the renal vein, the tumor expands and fills the proximal portion of the renal vein.

INK CODE: Perinephric fat - blue.

SECTION CODE: A1, ureter, renal artery, renal vein margins; A2-A3, tumor and renal vein; A4-A8, cystic portions of mass; A9-A10, tumor in relationship to perinephric fat, blue ink; A11-A12, tumor in relationship to renal sinus; A13, tumor and normal; A14, tumor; A15-A16, tumor in relationship to adrenal gland; A17, tumor; A18, representative sections of benign cortical cyst; A19, representative sections of normal renal parenchyma; A20, additional section of the tumor; A21-A25, additional sections of the renal vein and hilum

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

Source: NCI Genomic Data Commons file ebee8756-60a9-4572-b509-6f4afa839a37 (TCGA-KO-8404.06E8AA74-45F1-46E8-ADF8-84C69958EE5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).